Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TD, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TD-01A (Primary Tumor).

		10/29/12

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 J1 J2 B1 C1 D1 E1 E2 F1 F2 F3 G1 G2 H1 I1 I2 I3 I4 I5
I6 I7 I8 I9 I10 I11 I12 I13 I14 I15 I16
Left lower lobe lung (370.0 grams, 18.5 x 10.5 x 7.0 cm), station 3
lymph nodes, station 4R lymph nodes, station 4L lymph nodes, station
5 lymph nodes, station 7 lymph nodes (2 sets), station 9L lymph
nodes, station 10L lymph nodes, right tracheobronchial angle lymph
nodes.

DIAGNOSIS:

Lung, left lower lobe, lobectomy: Invasive grade 2-3 (of 4)
adenocarcinoma, forming a poorly-circumscribed 12.5 x 6.0 x 4.1 cm
peripheral mass, resembling a consolidated lobe. The tumor extends
to but not through the visceral pleura. Angiolymphatic invasion is
absent. The bronchial margin is negative for tumor. Multiple (2)
intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, intrapulmonary/hilar, excision:

- Metastatic adenocarcinoma is identified in one (of 1)
left hilar (station 10L) lymph node.

Lymph nodes, mediastinal, excision:

- Metastatic adenocarcinoma (microscopic subcapsular focus
<1 cm) is identified in a single (1 of 11) subcarinal (station 7)
lymph nodes.
- Metastatic adenocarcinoma is identified in multiple (2 of
3) left pulmonary ligament (station 9L) lymph nodes.
- No tumor is identified in multiple (8) prevascular and
retrotracheal (station 3) lymph nodes.
- No tumor is identified in multiple (6) right lower
paratracheal (station 4R) lymph nodes.
- No tumor is identified in multiple (3) left lower
paratracheal (station 4L) lymph nodes.
- No tumor is identified in multiple (2) sub-aortic
(station 5) lymph nodes.

Lymph nodes, right tracheobronchial angle, excision: A single (1)
right tracheobronchial angle lymph node is negative for tumor.

Photographed in lab.

1CD-0-3

adenocarcinoma, NOS 8/40/3
Site: lung, lower lobe C 34.3

hu
10/29/12

Source: NCI Genomic Data Commons file 2b0b4fcd-9c8d-4e6d-868a-240b318b789f (TCGA-MP-A4TD.12D870FD-E7C7-470B-9303-63495911A5FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).